Somatic mutation profile of tumor specimen ALCH-B3F0-TTP1-A (aliquot ALCH-B3F0-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3F0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.9 years (24,072 days).
Specimen ALCH-B3F0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 810f0ec7-506c-44fe-b69b-ce296414a920.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3F0-NB1-A (Blood Derived Normal), aliquot ALCH-B3F0-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afeaee8e-cd60-4658-bac8-dbbf7895e784

The open-access MAF lists 37 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, 3'UTR 2, Intron 2, Splice Region 1, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 44/345 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STK11 | c.180del p.Y60* | Frame Shift Del (DEL) | VAF 23/179 reads (13%) | catalogued as rs1555735008, CD064644, CM981863, CM991149, COSV58820509, COSV58821737, COSV58821906; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ALG2 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 82/503 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs879014518; called by muse, mutect2, varscan2
- C1orf167 | c.4214C>T p.T1405I | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.221); catalogued as rs1437412753; called by muse, mutect2, varscan2
- GABRA6 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 28/386 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs377498858; called by muse, mutect2
- MUS81 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs765092249, COSV100337403; called by muse, mutect2, varscan2
- MYH10 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768634600; called by muse, mutect2, varscan2
- NLGN4X | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 76/561 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.086); catalogued as rs1029475096, COSV52010253; called by muse, mutect2, varscan2
- NLRP10 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 36/327 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.344); catalogued as COSV60781427; called by muse, mutect2, varscan2
- RAPGEF3 | c.574G>A p.V192M (on ENST00000389212; = p.V150M on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs544361332; called by muse, mutect2, varscan2
- REG1B | c.64+5G>A | Splice Region (SNP) | VAF 13/111 reads (12%) | catalogued as COSV59305131; called by muse, mutect2, varscan2
- SH2D5 | c.808G>A p.A270T (on ENST00000444387 / NM_001103161.2; = p.A186T on NM_001103160.2) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); catalogued as rs373920480; called by muse, mutect2, varscan2
- THSD4 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs375872892; called by muse, mutect2, varscan2
- CASP8AP2 | c.4736G>T p.G1579V | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC97 | c.815T>C p.V272A | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- F8 | c.4019C>T p.P1340L | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- FGFRL1 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- IQCB1 | c.1105A>T p.S369C | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- MPP7 | c.1645A>G p.T549A | Missense Mutation (SNP) | VAF 35/347 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NETO1 | c.245T>A p.L82H | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NEURL1 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NKX2-1 | c.1018dup p.L340Pfs*69 | Frame Shift Ins (INS) | VAF 19/161 reads (12%) | called by mutect2, pindel, varscan2
- SHROOM3 | c.2405G>A p.G802D | Missense Mutation (SNP) | VAF 38/300 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TBX21 | c.1209C>A p.S403R | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ZKSCAN1 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 27/198 reads (14%) | called by muse, mutect2, varscan2
- C6orf118 | c.678C>T p.L226= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as rs906177327, COSV100024525; called by muse, mutect2, varscan2
- CDH1 | c.1773C>T p.N591= | Silent (SNP) | VAF 53/285 reads (19%) | catalogued as rs373719554, COSV55735575; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- H3C8 | c.27C>G p.R9= | Silent (SNP) | VAF 19/151 reads (13%) | catalogued as rs925881819; called by muse, varscan2
- HMGXB3 | c.1341A>G p.V447= (on ENST00000613459; = p.V201= on NM_014983.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/311 reads (13%) | called by muse, mutect2, varscan2
- LRP2 | c.13005A>G p.K4335= | Silent (SNP) | VAF 78/563 reads (14%) | called by muse, mutect2, varscan2
- MAP2 | c.2808C>T p.S936= | Silent (SNP) | VAF 33/194 reads (17%) | catalogued as rs570922955, COSV52307403; called by muse, mutect2, varscan2
- SLC12A5 | c.2757C>T p.S919= (on ENST00000454036 / NM_001134771.2; = p.S896= on NM_020708.5) | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as rs561222589; ClinVar: likely benign; called by muse, mutect2, varscan2
- SULF2 | c.1548C>T p.A516= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs202215339; called by mutect2, varscan2
- PKD1L2 | c.2778+61G>A | Intron (SNP) | VAF 23/204 reads (11%) | catalogued as rs771605471, COSV100216795; called by muse, mutect2, varscan2
- POU6F2 | c.18+27565C>T | Intron (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- RNF170 | c.*1413T>C | 3'UTR (SNP) | VAF 66/413 reads (16%) | catalogued as rs1236303664; called by muse, mutect2, varscan2
- SLC9A9 | c.*50G>C | 3'UTR (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2
